Somatic mutation profile of tumor specimen MMRF_2743_1_BM_CD138pos (aliquot MMRF_2743_1_BM_CD138pos_T1_KHS5U_L14897) from MMRF case MMRF_2743, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 42.8 years (15,616 days).
Specimen MMRF_2743_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e71f93d6-547d-4b7c-9c9d-dd40793ead7c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2743_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2743_1_PB_WBC_C3_KHS5U_L14898; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bd08bef7-6293-46d3-b786-81ab4a089c09

The open-access MAF lists 207 somatic variants for this specimen: 81 protein-altering or splice-affecting, 27 silent, 99 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 71, 3'UTR 50, Silent 27, Intron 20, 5'UTR 12, 3'Flank 9, 5'Flank 6, Nonsense Mutation 5, Frame Shift Del 3, RNA 2, In Frame Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD30B | c.3205C>T p.Q1069* | Nonsense Mutation (SNP) | VAF 19/101 reads (19%) | catalogued as COSV57702059; called by muse, mutect2, varscan2
- BTG1 | c.133C>T p.Q45* | Nonsense Mutation (SNP) | VAF 29/69 reads (42%) | catalogued as rs377174658; called by muse, varscan2
- BTG2 | c.133G>A p.A45T | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0.058); catalogued as rs1421706286, COSV51856494, COSV99305486; called by muse, mutect2, varscan2
- COL4A4 | c.3395C>T p.P1132L | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as CM030817; called by muse, mutect2, varscan2
- CPS1 | c.343C>A p.L115M | Missense Mutation (SNP) | VAF 89/247 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.017); catalogued as rs780976042; called by muse, mutect2, varscan2
- DNAH6 | c.8071C>T p.R2691W | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs556817208, COSV52850340; called by muse, mutect2, varscan2
- FBN2 | c.3393C>A p.C1131* | Nonsense Mutation (SNP) | VAF 232/442 reads (52%) | catalogued as COSV52546861; called by muse, mutect2, varscan2
- FCHO1 | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 57/145 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs1231657886, COSV53184509; called by muse, mutect2, varscan2
- FGF3 | c.574C>T p.R192W | Missense Mutation (SNP) | VAF 36/121 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV61925391; called by muse, mutect2, varscan2
- GPR31 | c.194C>T p.A65V | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as rs1335437298, COSV100834115, COSV64761123; called by muse, mutect2, varscan2
- H2BC12 | c.110G>A p.S37N | Missense Mutation (SNP) | VAF 45/236 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.027); catalogued as rs1265514538; called by muse, mutect2, varscan2
- HIVEP1 | c.7612C>G p.Q2538E | Missense Mutation (SNP) | VAF 168/322 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.438); catalogued as COSV65102950; called by muse, mutect2, varscan2
- IGHD | c.265A>G p.T89A | Missense Mutation (SNP) | VAF 26/42 reads (62%) | SIFT tolerated (0.71); PolyPhen benign (0.065); catalogued as rs766367805; called by muse, varscan2
- IGHD | c.58G>A p.D20N | Missense Mutation (SNP) | VAF 74/116 reads (64%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.006); catalogued as rs373837383; called by muse, varscan2
- IGLV3-22 | c.62A>T p.Y21F | Missense Mutation (SNP) | VAF 41/76 reads (54%) | SIFT tolerated (0.19); PolyPhen benign (0.103); catalogued as rs758080307; called by muse, varscan2
- IGLV3-22 | c.159G>A p.W53* | Nonsense Mutation (SNP) | VAF 81/145 reads (56%) | catalogued as rs771214189; called by muse, varscan2
- ITGA8 | c.973G>A p.V325I | Missense Mutation (SNP) | VAF 35/96 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as rs372255781; called by muse, mutect2, varscan2
- KCNT1 | c.121G>A p.A41T | Missense Mutation (SNP) | VAF 29/115 reads (25%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as COSV104404160, COSV53708747; called by muse, mutect2, varscan2
- PCDHA4 | c.2045C>T p.A682V | Missense Mutation (SNP) | VAF 151/282 reads (54%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.005); catalogued as rs1190740414; called by muse, mutect2, varscan2
- PPP1R14A | c.130C>T p.R44W | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV56646997; called by muse, mutect2, varscan2
- PRKAG3 | c.1337G>A p.R446K | Missense Mutation (SNP) | VAF 43/114 reads (38%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.993); catalogued as rs200750014; called by muse, mutect2, varscan2
- RAB17 | c.38C>T p.A13V | Missense Mutation (SNP) | VAF 60/161 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs1185140348; called by muse, mutect2, varscan2
- RASA2 | c.1532G>A p.R511H | Missense Mutation (SNP) | VAF 129/177 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1335975011, COSV53944275; called by muse, mutect2, varscan2
- RGL2 | c.224G>A p.R75Q | Missense Mutation (SNP) | VAF 122/452 reads (27%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs776653684; called by muse, mutect2, varscan2
- SCN1A | c.4699G>T p.E1567* (on ENST00000303395 / NM_001202435.3; = p.E1556* on NM_006920.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 61/150 reads (41%) | catalogued as rs1037225738; called by muse, mutect2, varscan2
- SLAMF7 | c.533C>T p.S178F | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV104420943, COSV63564100; called by muse, mutect2, varscan2
- SLC26A4 | c.262G>A p.V88I | Missense Mutation (SNP) | VAF 41/111 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs779745819, CM1111378, COSV55916347; called by muse, mutect2, varscan2
- SLC35E1 | c.451C>T p.L151F | Missense Mutation (SNP) | VAF 49/143 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.241); catalogued as rs767971575; called by muse, mutect2, varscan2
- SLC6A5 | c.1532C>A p.A511D | Missense Mutation (SNP) | VAF 82/178 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as COSV54232663; called by muse, mutect2, varscan2
- TENM2 | c.6724C>T p.R2242C (on ENST00000518659 / NM_001122679.2; = p.R2003C on NM_001080428.3) | Missense Mutation (SNP) | VAF 40/244 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777269622, COSV101317975, COSV69122800; called by muse, varscan2
- TIGD2 | c.524G>T p.G175V | Missense Mutation (SNP) | VAF 26/144 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as rs1342357726; called by muse, mutect2, varscan2
- TTLL5 | c.2248C>T p.H750Y | Missense Mutation (SNP) | VAF 49/124 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.176); catalogued as rs1352290245; called by muse, mutect2, varscan2
- UBAC1 | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 148/375 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); catalogued as rs762294104, COSV65614131; called by muse, mutect2, varscan2
- AC011448.1 | c.730dup p.A244Gfs*79 | Frame Shift Ins (INS) | VAF 12/58 reads (21%) | called by pindel, varscan2
- ADH7 | c.247A>T p.T83S | Missense Mutation (SNP) | VAF 124/333 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ATP8A2 | c.2827T>G p.F943V | Missense Mutation (SNP) | VAF 39/48 reads (81%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.652); called by muse, mutect2, varscan2
- C3orf33 | c.53T>A p.M18K | Missense Mutation (SNP) | VAF 29/40 reads (73%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CA2 | c.274_275del p.Q92Vfs*9 | Frame Shift Del (DEL) | VAF 20/89 reads (22%) | called by mutect2, pindel, varscan2
- CARD14 | c.2215T>A p.S739T | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated (0.39); PolyPhen benign (0.007); called by muse, mutect2
- CDH19 | c.1657G>T p.A553S | Missense Mutation (SNP) | VAF 74/208 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.029); called by muse, mutect2
- CDK13 | c.801_803del p.S270del | In Frame Del (DEL) | VAF 28/73 reads (38%) | called by pindel, varscan2
- CGNL1 | c.1856T>C p.L619S | Missense Mutation (SNP) | VAF 67/238 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- CYLC2 | c.453A>C p.K151N | Missense Mutation (SNP) | VAF 51/150 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- DSG2 | c.1728G>T p.Q576H | Missense Mutation (SNP) | VAF 25/124 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- DUSP9 | c.287A>G p.E96G | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FAT1 | c.9904T>C p.Y3302H | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FCRLB | c.353A>C p.E118A | Missense Mutation (SNP) | VAF 31/121 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- FREM2 | c.4882T>C p.F1628L | Missense Mutation (SNP) | VAF 97/166 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FSIP2 | c.11348C>T p.T3783I | Missense Mutation (SNP) | VAF 40/115 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- FZD10 | c.432C>A p.N144K | Missense Mutation (SNP) | VAF 160/474 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- GABRA4 | c.235T>C p.Y79H | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- HIBADH | c.488T>A p.V163E | Missense Mutation (SNP) | VAF 44/137 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.606); called by muse, mutect2, varscan2
- IGF2R | c.2254T>G p.F752V | Missense Mutation (SNP) | VAF 73/151 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGHA1 | c.390C>G p.H130Q | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT tolerated (0.8); PolyPhen benign (0.006); called by muse, varscan2
- IGHA1 | c.332C>T p.S111F | Missense Mutation (SNP) | VAF 33/62 reads (53%) | SIFT tolerated (0.4); PolyPhen benign (0.014); called by muse, varscan2
- IGHD | c.184A>G p.S62G | Missense Mutation (SNP) | VAF 45/75 reads (60%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, varscan2
- IGHG2 | c.343_352del p.A115Qfs*14 | Frame Shift Del (DEL) | VAF 23/105 reads (22%) | called by mutect2, pindel, varscan2
- IGLV3-25 | c.277A>T p.I93F | Missense Mutation (SNP) | VAF 42/109 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, varscan2
- ITGA5 | c.2059G>A p.G687S | Missense Mutation (SNP) | VAF 43/123 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- JPH3 | c.2180T>A p.I727N | Missense Mutation (SNP) | VAF 25/170 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); called by muse, mutect2, varscan2
- KSR1 | c.274C>G p.L92V | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.148); called by muse, mutect2, varscan2
- LRCH3 | c.2249G>T p.G750V | Missense Mutation (SNP) | VAF 31/165 reads (19%) | SIFT tolerated (0.12); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRRK1 | c.2320C>G p.L774V | Missense Mutation (SNP) | VAF 100/197 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- MEP1B | c.1592_1593del p.Y531Ffs*7 | Frame Shift Del (DEL) | VAF 35/107 reads (33%) | called by mutect2, pindel, varscan2
- MIB2 | c.1793T>C p.L598P | Missense Mutation (SNP) | VAF 48/104 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.739); called by muse, mutect2, varscan2
- OR14A2 | c.658T>G p.F220V | Missense Mutation (SNP) | VAF 62/168 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.469); called by muse, mutect2, varscan2
- PCDHA5 | c.791A>G p.N264S | Missense Mutation (SNP) | VAF 51/200 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- PDGFRA | c.1703A>G p.D568G | Missense Mutation (SNP) | VAF 95/262 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- PKDREJ | c.4781T>C p.F1594S | Missense Mutation (SNP) | VAF 7/146 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); called by muse, mutect2
- PLCE1 | c.6253G>T p.G2085C | Missense Mutation (SNP) | VAF 42/103 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- PTCHD1 | c.908G>T p.G303V | Missense Mutation (SNP) | VAF 50/136 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- RMI1 | c.1417T>G p.S473A | Missense Mutation (SNP) | VAF 16/164 reads (10%) | SIFT tolerated (0.83); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RTL9 | c.662T>C p.V221A | Missense Mutation (SNP) | VAF 87/247 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- SESN3 | c.583G>C p.V195L | Missense Mutation (SNP) | VAF 147/329 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- SLC34A2 | c.1682C>A p.P561H | Missense Mutation (SNP) | VAF 12/174 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- SYNE1 | c.21270G>C p.Q7090H (on ENST00000367255 / NM_182961.4; = p.Q7019H on NM_033071.3) | Missense Mutation (SNP) | VAF 12/244 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2
- TEX13C | c.9G>T p.M3I | Missense Mutation (SNP) | VAF 54/155 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TMEM255A | c.429A>G p.I143M | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- UACA | c.623G>A p.C208Y | Missense Mutation (SNP) | VAF 36/198 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ZBTB22 | c.1153G>A p.G385S | Missense Mutation (SNP) | VAF 36/224 reads (16%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- ZFP92 | c.977G>C p.G326A | Missense Mutation (SNP) | VAF 38/139 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- ADCYAP1 | c.381G>A p.P127= | Silent (SNP) | VAF 22/68 reads (32%) | called by muse, mutect2
- ALOX15 | c.351C>T p.G117= | Silent (SNP) | VAF 81/230 reads (35%) | catalogued as rs777383384; called by muse, mutect2, varscan2
- APOA4 | c.774C>T p.A258= | Silent (SNP) | VAF 121/222 reads (55%) | catalogued as COSV63360755; called by muse, mutect2, varscan2
- B4GALNT4 | c.1929C>T p.G643= | Silent (SNP) | VAF 9/39 reads (23%) | called by muse, mutect2, varscan2
- B4GALT5 | c.132C>T p.F44= | Silent (SNP) | VAF 76/202 reads (38%) | called by muse, mutect2, varscan2
- CEP85 | c.363A>G p.S121= | Silent (SNP) | VAF 42/107 reads (39%) | called by muse, mutect2, varscan2
- CNGA1 | c.48C>A p.P16= | Silent (SNP) | VAF 49/125 reads (39%) | catalogued as COSV100652298; called by muse, mutect2, varscan2
- CNN1 | c.717C>T p.D239= | Silent (SNP) | VAF 49/124 reads (40%) | called by muse, mutect2, varscan2
- CYP4A22 | c.1374C>T p.I458= | Silent (SNP) | VAF 32/107 reads (30%) | catalogued as rs397839812, COSV53738304; called by muse, mutect2, varscan2
- CYP4F12 | c.831C>T p.T277= | Silent (SNP) | VAF 91/280 reads (33%) | called by muse, mutect2, varscan2
- DUSP2 | c.354C>T p.T118= | Silent (SNP) | VAF 36/93 reads (39%) | called by muse, mutect2, varscan2
- GALP | c.174G>A p.K58= | Silent (SNP) | VAF 41/126 reads (33%) | catalogued as COSV62000591; called by muse, mutect2, varscan2
- IARS1 | c.1734C>T p.L578= | Silent (SNP) | VAF 53/218 reads (24%) | called by muse, mutect2, varscan2
- IGLV3-22 | c.219C>T p.Y73= | Silent (SNP) | VAF 106/156 reads (68%) | catalogued as rs552865385; called by muse, varscan2
- KHDRBS2 | c.420A>G p.P140= | Silent (SNP) | VAF 83/243 reads (34%) | catalogued as COSV99836510; called by muse, mutect2, varscan2
- KLHL14 | c.1680A>C p.R560= | Silent (SNP) | VAF 22/61 reads (36%) | called by muse, mutect2, varscan2
- MAGEB6B | c.492A>G p.S164= | Silent (SNP) | VAF 44/113 reads (39%) | called by muse, mutect2, varscan2
- MC3R | c.417C>T p.A139= | Silent (SNP) | VAF 80/242 reads (33%) | called by muse, mutect2, varscan2
- MROH7 | c.1005G>A p.E335= | Silent (SNP) | VAF 99/240 reads (41%) | called by muse, mutect2, varscan2
- NEDD4 | c.828C>T p.T276= | Silent (SNP) | VAF 11/280 reads (4%) | called by muse, mutect2
- NT5DC3 | c.909T>C p.S303= | Silent (SNP) | VAF 25/364 reads (7%) | called by muse, mutect2
- OR6M1 | c.249C>T p.L83= | Silent (SNP) | VAF 155/290 reads (53%) | called by muse, mutect2, varscan2
- PAOX | c.30C>T p.A10= | Silent (SNP) | VAF 8/28 reads (29%) | called by muse, mutect2, varscan2
- SOCS1 | c.195G>A p.R65= | Silent (SNP) | VAF 45/124 reads (36%) | catalogued as COSV59658721; called by muse, mutect2, varscan2
- SOX6 | c.2235T>C p.G745= (on ENST00000528429 / NM_001145819.2; = p.G718= on NM_017508.3) | Silent (SNP) | VAF 38/69 reads (55%) | catalogued as rs759780547; called by muse, mutect2, varscan2
- ZNF462 | c.1155C>T p.D385= | Silent (SNP) | VAF 122/271 reads (45%) | called by muse, mutect2, varscan2
- ZNF516 | c.1209C>T p.A403= | Silent (SNP) | VAF 23/125 reads (18%) | called by muse, mutect2, varscan2
- AC024651.2 | chr15:97874732 C>G | 5'Flank (SNP) | VAF 45/171 reads (26%) | called by muse, mutect2, varscan2
- ADCK2 | chr7:140696071 C>T | 3'Flank (SNP) | VAF 19/98 reads (19%) | catalogued as rs1348229668; called by muse, mutect2, varscan2
- AFF2 | c.*7628C>A | 3'UTR (SNP) | VAF 20/104 reads (19%) | catalogued as rs1557293787; called by muse, varscan2
- AL031777.2 | c.*343_*347del | 3'UTR (DEL) | VAF 97/371 reads (26%) | called by mutect2, pindel, varscan2
- ANXA1 | c.*211C>T | 3'UTR (SNP) | VAF 16/122 reads (13%) | called by muse, mutect2, varscan2
- ATP8B2 | c.*1697T>A | 3'UTR (SNP) | VAF 33/95 reads (35%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021005 A>G | 5'Flank (SNP) | VAF 50/150 reads (33%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021731 C>G | 5'Flank (SNP) | VAF 6/20 reads (30%) | called by muse, mutect2
- BDNF | c.*1127T>C | 3'UTR (SNP) | VAF 33/160 reads (21%) | called by muse, mutect2, varscan2
- BSDC1 | c.1261-772G>A | Intron (SNP) | VAF 31/120 reads (26%) | called by muse, mutect2, varscan2
- C12orf50 | c.1126+229C>T | Intron (SNP) | VAF 21/39 reads (54%) | called by muse, mutect2, varscan2
- CACNA1C | c.3829-596A>G | Intron (SNP) | VAF 55/170 reads (32%) | called by muse, mutect2, varscan2
- CACNA2D1 | chr7:81948917 T>G | 3'Flank (SNP) | VAF 53/130 reads (41%) | called by muse, mutect2, varscan2
- CAPN6 | c.*476G>T | 3'UTR (SNP) | VAF 39/102 reads (38%) | called by muse, mutect2, varscan2
- CEP78 | c.*6361A>G | 3'UTR (SNP) | VAF 7/178 reads (4%) | called by muse, mutect2
- CHRM3 | c.*1268G>A | 3'UTR (SNP) | VAF 27/74 reads (36%) | called by muse, mutect2, varscan2
- CRIM1 | c.*10A>C | 3'UTR (SNP) | VAF 149/434 reads (34%) | called by muse, mutect2, varscan2
- CXCL5 | c.*1053del | 3'UTR (DEL) | VAF 12/43 reads (28%) | catalogued as rs1005961925; called by mutect2, varscan2
- DCC | c.*3621G>T | 3'UTR (SNP) | VAF 25/91 reads (27%) | called by muse, mutect2, varscan2
- DDX5 | c.44+149T>C | Intron (SNP) | VAF 35/105 reads (33%) | catalogued as rs905756952; called by muse, mutect2, varscan2
- DIAPH2 | c.*1861C>G | 3'UTR (SNP) | VAF 10/83 reads (12%) | called by muse, mutect2, varscan2
- DPYD | c.483+1376A>C | Intron (SNP) | VAF 8/27 reads (30%) | called by mutect2, varscan2
- DSCAM | c.-434G>A | 5'UTR (SNP) | VAF 34/95 reads (36%) | called by muse, mutect2, varscan2
- EHD3 | c.*1186G>A | 3'UTR (SNP) | VAF 28/175 reads (16%) | catalogued as rs1219070946; called by muse, mutect2, varscan2
- FAM199X | c.*4632A>C | 3'UTR (SNP) | VAF 25/70 reads (36%) | called by muse, mutect2
- FAM234B | c.*762C>T | 3'UTR (SNP) | VAF 45/120 reads (38%) | catalogued as rs1207286052; called by muse, mutect2, varscan2
- GAPVD1 | chr9:125365648 ins T | 3'Flank (INS) | VAF 14/49 reads (29%) | called by mutect2, varscan2
- GLS | c.1650+2822A>C | Intron (SNP) | VAF 28/64 reads (44%) | catalogued as rs970948023; called by muse, mutect2, varscan2
- GNPTAB | c.*267G>T | 3'UTR (SNP) | VAF 20/49 reads (41%) | catalogued as rs779965656; called by muse, mutect2, varscan2
- GRM7 | c.*432C>A | 3'UTR (SNP) | VAF 63/83 reads (76%) | called by muse, mutect2, varscan2
- GRM7 | c.*884A>G | 3'UTR (SNP) | VAF 124/155 reads (80%) | called by muse, mutect2, varscan2
- GTF3C4 | c.*4136T>G | 3'UTR (SNP) | VAF 64/152 reads (42%) | called by muse, mutect2, varscan2
- HNRNPU | chr1:244851468 del CT | 3'Flank (DEL) | VAF 38/126 reads (30%) | catalogued as rs771652857; called by pindel, varscan2
- HTATIP2 | c.304-103C>T | Intron (SNP) | VAF 27/96 reads (28%) | called by muse, mutect2, varscan2
- ICE1 | c.*629_*630dup | 3'UTR (INS) | VAF 47/110 reads (43%) | called by mutect2, pindel, varscan2
- IFNA6 | c.*332A>T | 3'UTR (SNP) | VAF 6/44 reads (14%) | called by muse, mutect2, varscan2
- IGHV3-7 | c.-9G>C | 5'UTR (SNP) | VAF 18/69 reads (26%) | called by muse, varscan2
- IGLV3-21 | c.-56T>C | 5'UTR (SNP) | VAF 15/25 reads (60%) | catalogued as rs1370042523; called by muse, mutect2, varscan2
- IGSF5 | c.*139G>T | 3'UTR (SNP) | VAF 22/51 reads (43%) | called by muse, mutect2, varscan2
- IPCEF1 | c.*919dup | 3'UTR (INS) | VAF 47/85 reads (55%) | catalogued as rs911149934; called by mutect2, varscan2
- IQCE | c.*3955C>T | 3'UTR (SNP) | VAF 37/109 reads (34%) | called by muse, mutect2, varscan2
- IRX1 | c.*178G>A | 3'UTR (SNP) | VAF 14/49 reads (29%) | catalogued as rs1186618243; called by muse, mutect2, varscan2
- KLHL13 | c.99-637T>G | Intron (SNP) | VAF 25/71 reads (35%) | called by muse, mutect2, varscan2
- KREMEN1 | chr22:29143848 C>A | 3'Flank (SNP) | VAF 13/29 reads (45%) | called by muse, mutect2, varscan2
- LEPROT | c.*815A>T | 3'UTR (SNP) | VAF 4/51 reads (8%) | called by muse, mutect2
- LRFN4 | c.-234A>G | 5'UTR (SNP) | VAF 57/232 reads (25%) | called by muse, mutect2, varscan2
- LSM14B | c.*60G>A | 3'UTR (SNP) | VAF 70/178 reads (39%) | catalogued as rs1412585884; called by muse, mutect2, varscan2
- LUZP2 | c.*858A>T | 3'UTR (SNP) | VAF 63/126 reads (50%) | called by muse, mutect2, varscan2
- MAP3K4 | chr6:160991760 A>T | 5'Flank (SNP) | VAF 9/26 reads (35%) | called by muse, mutect2, varscan2
- MBD5 | c.*573T>A | 3'UTR (SNP) | VAF 32/92 reads (35%) | called by muse, mutect2, varscan2
- MCRS1 | c.11-205G>C | Intron (SNP) | VAF 16/68 reads (24%) | called by muse, mutect2, varscan2
- MLLT3 | c.*2227T>G | 3'UTR (SNP) | VAF 55/141 reads (39%) | called by muse, mutect2, varscan2
- MMAB | c.*748T>C | 3'UTR (SNP) | VAF 37/241 reads (15%) | called by muse, mutect2, varscan2
- MMP2 | c.-22C>T | 5'UTR (SNP) | VAF 11/47 reads (23%) | called by muse, mutect2, varscan2
- MOSPD1 | c.*700A>C | 3'UTR (SNP) | VAF 18/59 reads (31%) | called by muse, mutect2, varscan2
- MYO10 | c.279+2597T>A | Intron (SNP) | VAF 27/442 reads (6%) | called by muse, mutect2
- NAP1L2 | c.*376T>G | 3'UTR (SNP) | VAF 24/71 reads (34%) | called by muse, mutect2, varscan2
- NIPAL3 | c.1021+1273A>G | Intron (SNP) | VAF 22/55 reads (40%) | catalogued as rs1296906517; called by muse, varscan2
- NKAIN2 | c.*1521T>C | 3'UTR (SNP) | VAF 35/119 reads (29%) | called by muse, mutect2, varscan2
- NLRP4 | c.-1G>T | 5'UTR (SNP) | VAF 4/84 reads (5%) | catalogued as COSV100015791; called by muse, mutect2
- NPAP1 | c.*447G>A | 3'UTR (SNP) | VAF 105/188 reads (56%) | catalogued as rs1195348247; called by muse, mutect2, varscan2
- NT5DC3 | c.*3748C>T | 3'UTR (SNP) | VAF 22/63 reads (35%) | catalogued as rs537344718; called by muse, varscan2
- OTUD6B | c.*128C>G | 3'UTR (SNP) | VAF 42/106 reads (40%) | called by muse, mutect2, varscan2
- PCSK5 | c.-477C>T | 5'UTR (SNP) | VAF 16/87 reads (18%) | called by muse, mutect2, varscan2
- PDE10A | c.*767T>C | 3'UTR (SNP) | VAF 39/128 reads (30%) | called by muse, mutect2, varscan2
- PHKA2 | c.*311G>T | 3'UTR (SNP) | VAF 19/63 reads (30%) | called by muse, mutect2, varscan2
- PLPPR4 | c.*2100_*2101del | 3'UTR (DEL) | VAF 32/97 reads (33%) | called by mutect2, pindel, varscan2
- POLE2 | c.1074-86G>T | Intron (SNP) | VAF 6/12 reads (50%) | called by muse, mutect2
- PPP1R9A | c.*4100G>A | 3'UTR (SNP) | VAF 5/10 reads (50%) | catalogued as rs953776178; called by muse, mutect2
- PPP2R5C | c.-41C>T | 5'UTR (SNP) | VAF 50/125 reads (40%) | called by muse, mutect2, varscan2
- PPWD1 | c.300-704G>A | Intron (SNP) | VAF 47/400 reads (12%) | catalogued as rs1411671148; called by muse, mutect2, varscan2
- PRKRIP1 | c.*722C>T | 3'UTR (SNP) | VAF 45/125 reads (36%) | called by muse, mutect2, varscan2
- PRRX1 | c.*807G>C | 3'UTR (SNP) | VAF 24/71 reads (34%) | called by muse, mutect2, varscan2
- RAB34 | c.*223T>C | 3'UTR (SNP) | VAF 22/68 reads (32%) | called by muse, mutect2, varscan2
- RBBP7 | c.17-348T>A | Intron (SNP) | VAF 45/107 reads (42%) | called by muse, mutect2, varscan2
- RMND5B | c.*371A>T | 3'UTR (SNP) | VAF 135/257 reads (53%) | called by muse, mutect2, varscan2
- SBNO2 | c.-114C>T | 5'UTR (SNP) | VAF 4/48 reads (8%) | called by muse, mutect2
- SH2D3C | c.515+2738C>G | Intron (SNP) | VAF 7/115 reads (6%) | called by muse, mutect2
- SLC38A11 | c.-198A>G | 5'UTR (SNP) | VAF 14/44 reads (32%) | called by muse, mutect2, varscan2
- SLC6A8 | c.778-224C>T | Intron (SNP) | VAF 12/32 reads (38%) | catalogued as rs782223970; called by muse, mutect2
- SLITRK4 | chrX:143624694 A>G | 3'Flank (SNP) | VAF 16/64 reads (25%) | called by muse, mutect2, varscan2
- SMOC2 | c.-162C>A | 5'UTR (SNP) | VAF 30/54 reads (56%) | called by muse, mutect2, varscan2
- SOX11 | c.*2279C>T | 3'UTR (SNP) | VAF 19/47 reads (40%) | catalogued as COSV100431027, COSV100431039; called by muse, mutect2, varscan2
- SPANXN2 | c.-657A>C | 5'UTR (SNP) | VAF 105/266 reads (39%) | called by muse, mutect2
- SPATA31C2 | n.1166C>A | RNA (SNP) | VAF 126/265 reads (48%) | called by muse, mutect2, varscan2
- SSC4D | c.*93C>T | 3'UTR (SNP) | VAF 36/71 reads (51%) | called by muse, mutect2, varscan2
- STAG2 | chrX:124102576 C>A | 3'Flank (SNP) | VAF 11/35 reads (31%) | called by muse, mutect2, varscan2
- TBC1D25 | c.*1046A>G | 3'UTR (SNP) | VAF 57/139 reads (41%) | called by muse, mutect2, varscan2
- TDGF1P3 | n.438G>T | RNA (SNP) | VAF 78/213 reads (37%) | called by muse, mutect2, varscan2
- TEAD1 | c.*1296G>A | 3'UTR (SNP) | VAF 77/119 reads (65%) | catalogued as rs1018529145; called by muse, mutect2, varscan2
- TMEM144 | c.109+1102dup | Intron (INS) | VAF 17/58 reads (29%) | catalogued as rs1480254740; called by mutect2, varscan2
- TMEM242 | chr6:157323554 A>G | 5'Flank (SNP) | VAF 18/80 reads (23%) | called by muse, mutect2
- TMEM97 | c.*1375C>T | 3'UTR (SNP) | VAF 26/80 reads (33%) | catalogued as rs1259826189; called by muse, mutect2, varscan2
- TRAF3IP2 | chr6:111558697 A>C | 3'Flank (SNP) | VAF 12/19 reads (63%) | called by muse, mutect2, varscan2
- TRIM16 | chr17:15684201 C>G | 5'Flank (SNP) | VAF 16/34 reads (47%) | called by muse, mutect2, varscan2
- TTYH1 | c.126+327C>T | Intron (SNP) | VAF 5/95 reads (5%) | called by muse, mutect2
- UBR5 | c.8187+139T>G | Intron (SNP) | VAF 6/10 reads (60%) | called by muse, mutect2, varscan2
- UNC5D | c.1303+1809A>C | Intron (SNP) | VAF 68/180 reads (38%) | called by muse, mutect2, varscan2
- ZNF566 | chr19:36445498 G>T | 3'Flank (SNP) | VAF 16/44 reads (36%) | called by muse, varscan2
